Somatic mutation profile of tumor specimen C3N-00440-02 (aliquot CPT0379590007) from CPTAC case C3N-00440, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.7 years (19,619 days).
Specimen C3N-00440-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2813b236-5285-4447-bb22-02be927fd804.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00440-31 (Blood Derived Normal), aliquot CPT0379620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/010a8252-dfd3-40f7-82c9-391474c0572f

The open-access MAF lists 79 somatic variants for this specimen: 56 protein-altering or splice-affecting, 10 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 10, Intron 8, 5'UTR 4, Nonsense Mutation 3, Frame Shift Del 3, Splice Region 2, In Frame Ins 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3682G>A p.D1228N | Missense Mutation (SNP) | VAF 136/273 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913671, CM970946, COSV59256021, COSV59261249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDHR3 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs926905608; called by muse, mutect2, varscan2
- CNGB3 | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV60689981; called by muse, mutect2, varscan2
- CYP3A5 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 42/169 reads (25%) | catalogued as rs776567184; called by muse, mutect2, varscan2
- GAGE1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.317); catalogued as rs782247653; called by muse, mutect2, varscan2
- GRID2 | c.2063A>T p.Y688F | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV56266745; called by muse, mutect2, varscan2
- HTR1D | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV58447323, COSV58449474; called by muse, mutect2, varscan2
- IGLJ3 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1175526801; called by muse, varscan2
- LAMB4 | c.4683A>T p.K1561N | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99224917; called by muse, mutect2, varscan2
- MTIF3 | c.587del p.G196Efs*4 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as COSV63528707; called by mutect2, pindel, varscan2
- MUC16 | c.40193G>C p.R13398P | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs764581423, COSV66689492; called by muse, mutect2, varscan2
- MYOCD | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV58505927; called by muse, mutect2, varscan2
- PPM1E | c.1602C>G p.C534W | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs1458100513; called by muse, mutect2, varscan2
- RAD52 | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779195700; called by muse, mutect2, varscan2
- RNF123 | c.3565C>G p.L1189V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as COSV104395779; called by muse, mutect2, varscan2
- SLC22A8 | c.1529+7C>T | Splice Region (SNP) | VAF 69/197 reads (35%) | catalogued as COSV100268063; called by muse, mutect2, varscan2
- ZFAND2B | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs535919706, COSV54695533; called by muse, mutect2, varscan2
- ABCC11 | c.1330T>G p.S444A | Missense Mutation (SNP) | VAF 126/266 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHCYL2 | c.948C>G p.H316Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ANKLE2 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARHGAP35 | c.3973T>G p.F1325V | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- BBS4 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 103/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CCDC33 | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CFHR3 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 86/140 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CISH | c.199C>G p.L67V (on ENST00000348721 / NM_145071.4; = p.L84V on NM_013324.6) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CORO7 | c.1578G>A p.E526= | Splice Region (SNP) | VAF 34/142 reads (24%) | called by muse, mutect2, varscan2
- EHBP1 | c.2008G>T p.G670* | Nonsense Mutation (SNP) | VAF 69/226 reads (31%) | called by muse, mutect2, varscan2
- EPG5 | c.4235A>C p.E1412A | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FAM240A | c.53C>A p.T18N (on ENST00000444264; = p.T12N on NM_001195442.2) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FAM83G | c.2249A>G p.Q750R | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FUT2 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GALNT14 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNPTAB | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HYDIN | c.12537dup p.L4180Ifs*32 | Frame Shift Ins (INS) | VAF 28/196 reads (14%) | called by mutect2, pindel, varscan2
- IDH1 | c.818_819insATA p.D273delinsEY | In Frame Ins (INS) | VAF 69/253 reads (27%) | called by mutect2, pindel, varscan2
- KDM6A | c.761del p.H254Pfs*3 | Frame Shift Del (DEL) | VAF 51/100 reads (51%) | called by mutect2, pindel, varscan2
- KIF1A | c.2899G>C p.A967P | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KLHL30 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | called by mutect2, varscan2
- LRP1B | c.13471G>T p.G4491C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRD1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- MYL3 | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 145/468 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NHSL1 | c.3878C>T p.P1293L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NSMCE4A | c.620del p.N207Tfs*35 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
- PGK2 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- PIK3CG | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- RBM39 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- REV3L | c.6068C>G p.P2023R | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC36A4 | c.1173A>C p.E391D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STRN4 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TAF1C | c.1861T>A p.C621S | Missense Mutation (SNP) | VAF 107/490 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMPRSS11D | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM11 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TSPAN14 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS52 | c.1951T>C p.S651P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFYVE16 | c.3171T>A p.H1057Q | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF229 | c.642A>C p.K214N | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- AFDN | c.471C>T p.F157= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV60036260; called by muse, mutect2, varscan2
- CBLL2 | c.306A>G p.R102= | Silent (SNP) | VAF 76/127 reads (60%) | called by muse, mutect2, varscan2
- LEMD3 | c.936A>G p.G312= | Silent (SNP) | VAF 61/214 reads (29%) | called by mutect2, varscan2
- NYAP2 | c.1200C>T p.A400= | Silent (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- OGDH | c.768C>G p.A256= | Silent (SNP) | VAF 94/185 reads (51%) | called by muse, mutect2, varscan2
- OR2F1 | c.114C>T p.T38= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as rs754332552, COSV67331947; called by muse, mutect2, varscan2
- PWWP2A | c.1896C>A p.S632= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV61046297; called by muse, mutect2, varscan2
- SMARCC2 | c.1476T>A p.G492= | Silent (SNP) | VAF 43/127 reads (34%) | called by muse, mutect2, varscan2
- USP19 | c.840G>T p.V280= | Silent (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- ZNF786 | c.1029C>T p.G343= | Silent (SNP) | VAF 70/130 reads (54%) | catalogued as rs1345951774; called by muse, mutect2, varscan2
- CCDC30 | c.385-8195T>C | Intron (SNP) | VAF 53/178 reads (30%) | called by muse, mutect2, varscan2
- FAM47E-STBD1 | c.-18C>A | 5'UTR (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- LILRB4 | c.-12G>A | 5'UTR (SNP) | VAF 61/209 reads (29%) | catalogued as rs201956451; called by muse, mutect2, varscan2
- LILRB5 | c.1255+88G>A | Intron (SNP) | VAF 14/48 reads (29%) | catalogued as rs561852057; called by muse, mutect2, varscan2
- NPHP3 | c.-40del | 5'UTR (DEL) | VAF 39/176 reads (22%) | called by mutect2, pindel, varscan2
- NR6A1 | c.142+40796del | Intron (DEL) | VAF 40/174 reads (23%) | called by mutect2, varscan2
- NR6A1 | c.142+40795del | Intron (DEL) | VAF 34/207 reads (16%) | called by mutect2*, pindel, varscan2*
- NUP214 | c.-45C>T | 5'UTR (SNP) | VAF 9/80 reads (11%) | catalogued as rs202135305; called by muse, varscan2
- PTPA | c.999+838T>C | Intron (SNP) | VAF 70/230 reads (30%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.3835+71del | Intron (DEL) | VAF 32/154 reads (21%) | called by mutect2, pindel, varscan2
- SPPL2B | c.956+318C>T | Intron (SNP) | VAF 101/324 reads (31%) | catalogued as rs1267457882; called by muse, mutect2, varscan2
- USE1 | c.152+9A>G | Intron (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- ZNF99 | c.*777C>A | 3'UTR (SNP) | VAF 71/279 reads (25%) | catalogued as COSV101233757; called by muse, mutect2, varscan2
